Somatic mutation profile of tumor specimen MP2PRT-PARRRW-TMP1-A (aliquot MP2PRT-PARRRW-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PARRRW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,438 days).
Specimen MP2PRT-PARRRW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f0243f1-bc73-4bca-8657-3ea4d4736d0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARRRW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARRRW-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5c3fc75-dcfd-4f6e-ad9b-13e15d6df33f

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 10, Silent 4, Nonsense Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 45/178 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.7625C>T p.T2542M | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs80358989, COSV66461826; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- FLT3 | c.2501G>A p.R834Q | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54061573; called by muse, mutect2, varscan2
- GASK1A | c.1268C>T p.A423V | Missense Mutation (SNP) | VAF 122/257 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs931471430, COSV56183402, COSV56184812; called by muse, mutect2, varscan2
- CXorf66 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- HPF1 | c.174G>T p.K58N | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- KLHL26 | c.455G>A p.C152Y | Missense Mutation (SNP) | VAF 110/288 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- MEOX2 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- NCOA2 | c.1336G>A p.G446R | Missense Mutation (SNP) | VAF 241/406 reads (59%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- NTRK2 | c.2431G>T p.A811S (on ENST00000323115 / NM_001369534.1; = p.A827S on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 67/163 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- SLC22A6 | c.1258T>C p.S420P | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TLL1 | c.1178C>T p.T393M | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- F2R | c.861G>A p.T287= | Silent (SNP) | VAF 93/245 reads (38%) | catalogued as rs780737633, COSV59928363; called by muse, mutect2, varscan2
- FANCB | c.1773T>C p.S591= | Silent (SNP) | VAF 85/187 reads (45%) | called by muse, mutect2, varscan2
- HAS3 | c.597G>A p.T199= | Silent (SNP) | VAF 67/164 reads (41%) | catalogued as rs141994861, COSV99544365; called by muse, mutect2, varscan2
- PRUNE2 | c.246C>T p.S82= | Silent (SNP) | VAF 80/205 reads (39%) | catalogued as rs759035052, COSV100943023; called by muse, mutect2, varscan2
